Somatic mutation profile of tumor specimen TCGA-CV-7429-01A (aliquot TCGA-CV-7429-01A-11D-2129-08) from TCGA case TCGA-CV-7429, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 55.3 years (20,188 days).
Specimen TCGA-CV-7429-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 620d7e2d-5fe6-4141-9abb-dfe22cc7acf2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7429-10A (Blood Derived Normal), aliquot TCGA-CV-7429-10A-01D-2129-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74510ebc-d70d-48e0-b9c2-da5d80e15b01

The open-access MAF lists 57 somatic variants for this specimen: 41 protein-altering or splice-affecting, 16 silent.
By variant classification: Missense Mutation 34, Silent 16, Nonsense Mutation 4, Splice Site 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.241G>T p.G81C | Missense Mutation (SNP) | VAF 52/126 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67960075, COSV67960449, COSV67960680; called by muse, mutect2, varscan2
- ARHGEF12 | c.4417G>A p.E1473K | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.202); catalogued as rs1486039186, COSV100754663; called by muse, mutect2, varscan2
- ARID1A | c.2338C>T p.Q780* | Nonsense Mutation (SNP) | VAF 24/97 reads (25%) | catalogued as COSV61373097; called by muse, mutect2, varscan2
- ATXN2 | c.3685C>T p.H1229Y (on ENST00000550104; = p.H1069Y on NM_002973.4) | Missense Mutation (SNP) | VAF 46/326 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57982584; called by muse, mutect2, varscan2
- C1orf35 | c.713G>T p.C238F | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); catalogued as COSV99683042; called by muse, mutect2, varscan2
- CC2D1A | c.2731C>T p.R911W | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV54308652, COSV99583051; called by muse, mutect2, varscan2
- CNGA4 | c.1226C>A p.A409E | Missense Mutation (SNP) | VAF 44/213 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.027); catalogued as COSV66005273, COSV66005813; called by muse, mutect2, varscan2
- CREB3L3 | c.1198G>A p.G400R | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs775793810, COSV99313868; called by muse, mutect2, varscan2
- CREBBP | c.5457C>A p.C1819* | Nonsense Mutation (SNP) | VAF 32/137 reads (23%) | catalogued as COSV52123268; called by muse, mutect2, varscan2
- CSH2 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as rs1446881129, COSV61080942; called by muse, mutect2, varscan2
- FRMD8 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV100454582; called by muse, mutect2
- HGF | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55949909; called by muse, mutect2, varscan2
- HS3ST2 | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 43/185 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746835350, COSV54457793; called by muse, mutect2, varscan2
- HS3ST5 | c.460G>C p.E154Q | Missense Mutation (SNP) | VAF 29/187 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100450296, COSV57147608; called by muse, mutect2
- ITPKC | c.1606C>T p.R536C | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as rs770860069, COSV99648463; called by muse, mutect2
- KLHL31 | c.746A>G p.K249R | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as COSV100911726; called by muse, mutect2, varscan2
- KSR1 | c.664G>A p.A222T (on ENST00000644974 / NM_001367810.1; = p.A85T on NM_014238.2) | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs1030882277, COSV52037376; called by mutect2, varscan2
- MYH4 | c.264C>G p.I88M | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.405); catalogued as rs1174174343, COSV55118571, COSV99700372; called by muse, mutect2, varscan2
- OR2L13 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV63560079; called by muse, mutect2, varscan2
- PLP2 | c.420T>A p.H140Q | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as rs1557099572; called by muse, mutect2
- PTX4 | c.1291G>A p.D431N (on ENST00000447419 / NM_001328608.2; = p.D426N on NM_001013658.1) | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.241); catalogued as rs371016282; called by muse, mutect2, varscan2
- QKI | c.528G>T p.K176N | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.055); catalogued as rs765523224, COSV99274297; called by muse, mutect2, varscan2
- RAPGEF3 | c.1048G>T p.E350* (on ENST00000389212; = p.E308* on NM_006105.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 31/130 reads (24%) | catalogued as COSV99405828; called by muse, mutect2, varscan2
- RUNX3 | c.502C>T p.R168* | Nonsense Mutation (SNP) | VAF 13/85 reads (15%) | catalogued as COSV58245060; called by muse, mutect2, varscan2
- SART3 | c.2839C>G p.Q947E (on ENST00000228284; = p.Q929E on NM_014706.4) | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV57207258, COSV99933853; called by muse, mutect2, varscan2
- SF3B3 | c.3032G>C p.W1011S | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV100209586; called by muse, mutect2, varscan2
- SMC1A | c.1796G>A p.R599H | Missense Mutation (SNP) | VAF 35/50 reads (70%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as COSV100447041; called by muse, mutect2, varscan2
- SP140 | c.1745C>A p.T582N | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0.405); catalogued as COSV100613391, COSV100614017; called by muse, mutect2, varscan2
- TAF5 | c.1157T>G p.L386W | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100674584; called by muse, mutect2, varscan2
- TJP3 | c.968G>T p.S323I | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.165); catalogued as COSV99515759; called by muse, mutect2, varscan2
- TMCO1 | c.476+2T>C p.X159_splice (on ENST00000612311 / NM_001256164.1; = p.X108_splice on NM_019026.6) | Splice Site (SNP) | VAF 5/75 reads (7%) | catalogued as COSV63318039; called by muse, mutect2
- TMEM207 | c.180G>T p.L60F | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV100718917; called by muse, mutect2, varscan2
- TNFSF13 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV99547115; called by muse, mutect2, varscan2
- U2AF1L4 | c.628C>T p.R210W (on ENST00000412391; = p.I151= on NM_144987.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/192 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1322578474, COSV53076736; called by muse, mutect2, varscan2
- UNC80 | c.177T>A p.H59Q | Missense Mutation (SNP) | VAF 58/199 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as COSV99778491; called by muse, mutect2, varscan2
- VPS13D | c.296A>G p.D99G | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.026); catalogued as rs1267012436, COSV100692539; called by muse, mutect2, varscan2
- ZFAT | c.1797G>T p.L599F | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as COSV100914247; called by muse, mutect2, varscan2
- ZFP64 | c.85G>T p.D29Y | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99401963; called by muse, mutect2, varscan2
- ZNF783 | c.613C>T p.R205W | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as rs749916281, COSV65185383; called by muse, mutect2, varscan2
- FSTL5 | c.2069del p.N690Ifs*4 | Frame Shift Del (DEL) | VAF 15/71 reads (21%) | called by mutect2, pindel, varscan2
- NUFIP2 | c.941dup p.F315Vfs*2 | Frame Shift Ins (INS) | VAF 35/119 reads (29%) | called by mutect2, pindel, varscan2
- CDH23 | c.8925C>T p.F2975= | Silent (SNP) | VAF 26/137 reads (19%) | catalogued as COSV99818935; called by muse, mutect2, varscan2
- COL6A1 | c.1233C>T p.D411= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs140478280, COSV62612730; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- FAN1 | c.201T>C p.N67= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as COSV100755826; called by muse, mutect2, varscan2
- FLAD1 | c.1542C>T p.I514= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs1035429728, COSV99422088; called by muse, mutect2, varscan2
- HECTD4 | c.6456C>T p.A2152= | Silent (SNP) | VAF 44/172 reads (26%) | catalogued as rs370476121, COSV66399208; called by muse, mutect2, varscan2
- KCNJ2 | c.1041T>G p.T347= | Silent (SNP) | VAF 24/170 reads (14%) | catalogued as COSV99696211; called by muse, mutect2, varscan2
- PATJ | c.2232T>C p.C744= | Silent (SNP) | VAF 42/125 reads (34%) | catalogued as COSV100333192; called by muse, mutect2, varscan2
- RPP30 | c.114C>A p.I38= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as COSV99520642; called by muse, mutect2, varscan2
- SAP30L | c.180C>A p.L60= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV99770345; called by muse, mutect2, varscan2
- SASS6 | c.1923G>A p.A641= | Silent (SNP) | VAF 63/195 reads (32%) | catalogued as rs770629923, COSV54930932; called by muse, mutect2, varscan2
- SPATA25 | c.48C>T p.S16= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as rs535223101, COSV51943408; called by muse, mutect2, varscan2
- TRAJ27 | c.33G>A p.G11= | Silent (SNP) | VAF 78/294 reads (27%) | called by muse, mutect2, varscan2
- TRAP1 | c.723C>T p.I241= | Silent (SNP) | VAF 20/79 reads (25%) | catalogued as rs748044609, COSV99893105; called by muse, mutect2, varscan2
- TTN | c.13464A>G p.T4488= (on ENST00000591111; = p.T3561= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/88 reads (31%) | catalogued as COSV100594879; called by muse, mutect2, varscan2
- UGT2B7 | c.9G>A p.V3= | Silent (SNP) | VAF 16/98 reads (16%) | catalogued as COSV100535107; called by muse, mutect2, varscan2
- USH1C | c.492G>A p.V164= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as COSV50014929; called by muse, mutect2
